Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JW, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JW-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: M
ADM DATE:

OPER DATE:

PROCEDURE: SPHS

year-old with right adrenal cancer. Operative Procedure: Bxp.

PROCEDURE: SPGD

1. "Left lobe of liver"

A 0.5 cm brown bit.

Frozen section control.

2. "Right adrenal gland"

Received in a large container is a 251 gram, 8.6 x 7.1 x 6.3 cm mass with attached fibroadipose tissue and residual adrenal gland. After trimming residual adrenal gland = 2.9 grams; tumor = 200 grams. The mass is covered by an intact pseudocapsule. Brown and tacky yellow stranding on cut surfaces. Focal pale tan nodular areas. Gross margins free.

2A. Residual adrenal.

2B-C. Pale areas.

2D. Variably pale areas.

2E-F. Brown areas with focal orange.

FROZEN SECTION REPORT

1. Benign hepatic parenchyma with steatosis (negative for carcinoma).

have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE: SPDX

1. Left lobe of liver, biopsy: Benign hepatic parenchyma with steatosis, negative for carcinoma.

2. Right adrenal gland, resection: High grade adrenal cortical carcinoma, characterized by necrosis and a high mitotic rate. Tumor is confined to the adrenal gland without extraglandular extension.

the signing staff pathologist, have personally

ICD-O-3
Carcinoma, Adrenal cortical
8370/3
Site Adrenal Gland cortex
C74.0
9/11/13

Source: NCI Genomic Data Commons file c1f2ac38-4802-4688-9dfa-e61b58ab16a7 (TCGA-OR-A5JW.54BAF12C-F096-4415-BFF0-DD35D22E932B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).